Surgical pathology report (de-identified scan), TCGA case TCGA-DB-5275, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Mayo Clinic - Rochester, specimen TCGA-DB-5275-01A (Primary Tumor).

[page 1 of 2]
1.1 Diagnosis:

Brain, right temporal lobe, excision: Negative for tumor.

TCGA-DB-5275

Brain, right temporal tumor, excisions #1 and #2: Grade 3 (of 4) oligoastrocytoma (WHO, grade III).

FISH studies for 1p and 19q deletion will be performed and reported as an addendum.

ADDENDA:

1p and 19q FISH studies were performed on cells within paraffin sections from tumor. Two hybridizations were performed: one with a 19q probe/control 19p pair and one with a 1p probe/control 1q pair. The 19q and 1p probes mapped to the regions that are commonly deleted in gliomas. The 19q to 19p probe ratio was 0.56. The 1p to 1q probe ratio was 1.02. For both probes, the normal ratio is approximately 1. Any ratio less than 0.80 is consistent with deletion of the chromosomal region of interest.

The results are less than the normal range and suggest deletion of 19q. Approximately 90% of cells had 2 copies of the 19q probe and 3-4 copies of the 19p probe, consistent with relative loss of 19q. In addition, approximately 80% of cells had 3-4 copies of the 1p and 1q probe. The results have been observed in other glioma specimens with tumor aneuploidy (or polyploidy) and relative loss of 19q.

This test was developed and its performance characteristics determined by Laboratory Medicine and Pathology,

[page 2 of 2]
[REDACTED]. It has not been cleared or approved by the U.S. Food and Drug Administration, and is to be used as an adjunct to existing clinical and pathological information. This test does not rule out other chromosome anomalies.

[REDACTED]

[REDACTED]

Preliminary Frozen Section Consultation:

Brain, right temporal lobe, excision: Negative for tumor.

Brain, right temporal tumor, excisions #1 and #2: Diffuse glioma, hold for final typing and grading.

Gross Description:

Right temporal lobe brain (3.4 x 2.3 x 0.8 cm) and right temporal tumor (#1: 4.7 x 3.6 x 1.1 cm, aggregating and #2: 6.0 x 6.0 x 2.5 cm)

Block Summary:

Part A: RT TEMPORAL LOBE

- 1 rt temp lobe
- 2 rt temp lobe
- 3 rt temp lobe

Part B: RT TEMPORAL TISSUE

- 1 Rt temporal tiss
- 2 Rt temporal tiss
- 3 Rt temporal tiss
- 4 Rt temporal tiss
- 5 Rt temporal tiss
- 6 Rt temporal tiss
- 7 Rt temporal tiss
- 8 Rt temporal tiss
- 9 Rt temporal tiss

Part C: RT TEMPORAL TISSUE #2

- 1 Rt temporal tiss #2
- 2 Rt temporal tiss #2
- 3 Rt temporal tiss #2
- 4 Rt temporal tiss #2
- 5 Rt temporal tiss #2
- 6 Rt temporal tiss #2
- 7 Rt temporal tiss #2
- 8 Rt temporal tiss #2
- 9 Rt temporal tiss #2
- 10 Rt temporal tiss #2
- [REDACTED]

END OF REPORT

Page 2 of 2

Source: NCI Genomic Data Commons file ee7a3dc6-ddb4-444a-bf05-21bcbc470c99 (TCGA-DB-5275.A034B295-7764-4732-94EA-A11A467642DD.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).